Somatic mutation profile of tumor specimen TCGA-EJ-7115-01A (aliquot TCGA-EJ-7115-01A-11D-2114-08) from TCGA case TCGA-EJ-7115, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.7 years (23,986 days).
Specimen TCGA-EJ-7115-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53e806af-c349-4bf3-94b6-db11dff1e5bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7115-10A (Blood Derived Normal), aliquot TCGA-EJ-7115-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/632010fd-f962-4df0-8e46-0f92822847f6

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Nonsense Mutation 5, Frame Shift Del 3, Splice Region 2, Splice Site 1, In Frame Del 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAL | c.1060G>A p.V354M (on ENST00000269162 / NM_001142339.3; = p.V431M on NM_182978.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as rs1064794741, COSV52330305; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPS6KA4 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 16/143 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV53700569; called by muse, mutect2, varscan2
- SPOP | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 58/203 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1057519968, COSV61652911, COSV61653817; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs747375312, COSV53181431; called by muse, mutect2, varscan2
- ADORA1 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs201646414, COSV55143318; called by muse, mutect2, varscan2
- ALX4 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 35/129 reads (27%) | catalogued as rs1156752533, COSV61326517; called by muse, mutect2, varscan2
- CFAP65 | c.407G>C p.R136T (on ENST00000341552 / NM_194302.4; = p.R71T on NM_152389.4) | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs778913827, COSV55390226, COSV55390960; called by muse, mutect2, varscan2
- CYTIP | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV51634703; called by muse, mutect2, varscan2
- DGKZ | c.2204A>G p.H735R (on ENST00000454345 / NM_001105540.2; = p.H547R on NM_003646.4) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV58991560; called by muse, mutect2, varscan2
- ETV3 | c.265A>T p.K89* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV58748295; called by muse, mutect2, varscan2
- EZH1 | c.1147A>G p.T383A | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV70550084; called by muse, mutect2, varscan2
- FILIP1 | c.2901T>G p.S967R | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.158); catalogued as COSV52735287, COSV99385432; called by muse, mutect2, varscan2
- FRG1 | c.22A>T p.K8* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV57004632; called by muse, mutect2, varscan2
- GPBP1L1 | c.631T>A p.S211T | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV51971148; called by muse, mutect2
- HJV | c.586A>C p.N196H (on ENST00000336751 / NM_213653.4; = p.N83H on NM_145277.5) | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60952581; called by muse, mutect2, varscan2
- HSF1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs369608182; called by mutect2, varscan2
- KANSL1L | c.1089T>C p.V363= | Splice Region (SNP) | VAF 33/134 reads (25%) | catalogued as rs1378361695, COSV55994239; called by muse, mutect2, varscan2
- KLHL2 | c.1468+2T>C p.X490_splice | Splice Site (SNP) | VAF 19/73 reads (26%) | catalogued as COSV56979927; called by muse, mutect2, varscan2
- MRGPRX2 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV61674556; called by muse, mutect2
- PADI3 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs146396025; called by muse, mutect2, varscan2
- PCDH18 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 51/192 reads (27%) | catalogued as COSV100787522, COSV61270183; called by muse, mutect2, varscan2
- PCYOX1L | c.825G>A p.E275= | Splice Region (SNP) | VAF 34/142 reads (24%) | catalogued as rs1222022679, COSV51003740; called by muse, mutect2, varscan2
- PTPRO | c.2599G>T p.E867* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV55516049; called by muse, mutect2, varscan2
- SCUBE2 | c.1846A>G p.K616E | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.741); catalogued as COSV58544576; called by muse, mutect2, varscan2
- SIPA1 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67746139; called by muse, mutect2
- SLC4A7 | c.1620T>G p.S540R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV55399974; called by muse, mutect2, varscan2
- SPAG1 | c.1036A>T p.N346Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV52561268; called by muse, mutect2, varscan2
- TACR1 | c.390G>C p.R130S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59483809; called by muse, mutect2, varscan2
- TCF4 | c.1484G>A p.R495K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.745); catalogued as COSV61901319; called by muse, mutect2, varscan2
- CREBBP | c.6597_6609del p.Q2199Hfs*99 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- GGCX | c.2228_2231del p.H743Lfs*98 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- LMAN1L | c.60_61del p.H21Qfs*3 | Frame Shift Del (DEL) | VAF 29/157 reads (18%) | called by mutect2, pindel, varscan2
- MAP3K7 | c.1772_1774del p.Q591del (on ENST00000369329 / NM_145331.3; = p.Q564del on NM_003188.4) | In Frame Del (DEL) | VAF 16/107 reads (15%) | called by pindel, varscan2
- ASCC3 | c.3150A>G p.V1050= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV61231007; called by muse, mutect2, varscan2
- C1orf146 | c.273G>A p.L91= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV64861013; called by muse, mutect2, varscan2
- LACC1 | c.1137T>C p.I379= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV57829460; called by muse, mutect2
- PLXNB3 | c.3402C>T p.A1134= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV62799619; called by muse, mutect2, varscan2
- PRDM16 | c.1881C>T p.S627= | Silent (SNP) | VAF 39/161 reads (24%) | catalogued as rs746328459, COSV54598830; called by muse, mutect2, varscan2
- PRMT6 | c.690C>T p.L230= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV63655937; called by muse, mutect2, varscan2
- SLC25A46 | c.984C>T p.D328= | Silent (SNP) | VAF 22/432 reads (5%) | catalogued as rs767826203, COSV63506900; called by muse, mutect2
- POM121 | chr7:72949394 C>A | 3'Flank (SNP) | VAF 6/67 reads (9%) | catalogued as COSV57519849; called by muse, mutect2
- VKORC1 | c.*2C>A | 3'UTR (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99762016; called by muse, mutect2, varscan2
